Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A76X, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A76X-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY:

PROCEDURE DATE:

RECEIVED DATE:

REPORT DATE:

COPY TO:

CCF ICD-O-3
Adenocarcinoma, acinar
8/40/3

path
Adenocarcinoma NOS
8/40/3

Site: Prostate NOS
c61.9
8/19/13

Pre-Op Diagnosis

Prostate cancer

Post-Op Diagnosis

Same

Clinical History

Nothing indicated on requisition

Gross Description:

Container labeled [REDACTED] - prostate and pelvic lymph node biopsy" is a previously inked previously partially sectioned moderately distorted prostate gland with attached bilateral seminal vesicles weighing as received 37 grams. The prostate gland on reconstruction measures approximately 4.8 x 3.7 x 3.7 cm and has a slightly lobulated focally shaggy outer surface. The urethra appears to be compressed by the lateral lobes but is grossly patent.

The specimen is received after tissue harvest for genomic study. Within the specimen container are two tissue cassettes labeled

" As previously sectioned there is multi-nodular tan gray fibrotic lateral lobes. In the mid to proximal (vesical) region there is a poorly defined approximately 2.5 x 2.5 x 1.5 cm area of slightly indurated tan gray fibrosis occupying the left lateral and left posterior lobe extending focally to within 0.1 cm of the nearest outer surface margin. This is poorly defined, however, the urethra appears to be displaced toward the right lateral aspect in this distal area. This grossly appears to focally extend to within 0.3 cm of the vesical (proximal) margin.

The seminal vesicles together are 5.2 x 2.0 x 1.1 cm. Each has a lobulated gray tan outer surface with a multi-cystic gray tan fibrotic cut surface. No gross lesion is identified. Also received in the same container is a 4.1 x 2.6 x 1.2 cm portion of tan yellow fibroadipose tissue which on palpation and sectioning reveals a single poorly defined 2.6 cm tan yellow nodule. Representative

[page 2 of 2]
sections are submitted labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle; S and T - nodule from separate adipose tissue bisected.

Microscopic Description:
See diagnosis.

Final Diagnosis

Prostate and pelvic lymph node biopsy, radical prostatectomy:

Tumor characteristics:

Histologic type: Prostatic adenocarcinoma.

Prostate size: 37 grams with attached seminal vesicles.

Tumor quantitation:

Tumor involves right and left lobes.

Tumor measures up to 2 cm as measured on glass slide.

Gleason grade:

Primary pattern: 3/5

Secondary pattern: 4/5

Total score: 7/10

Extra prostatic extension: No.

Seminal vesicle involvement: Not present.

Lymphovascular space invasion: Not identified.

High grade PIN: Not identified.

Treatment effect: Not known.

Surgical margin status:

Margins uninvolved: Distal apical and proximal margins negative.

Soft tissue margin negative.

Lymph node status:

Total number of lymph nodes received: One

Total number of lymph nodes containing metastatic carcinoma: Zero

(0/1)

Other significant findings:

pTN stage: pT2N0 PAS 9

CPT: 88309

This report has been finalized at the
Dr. Signature>

<Sign Out

Reviewed (Initials):	KMS	8/2/13

Source: NCI Genomic Data Commons file bae5309b-0b94-4b75-8c89-385e59594322 (TCGA-HC-A76X.DA72A108-04AA-424B-83EE-714036869E87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).